Somatic mutation profile of tumor specimen TCGA-A3-3387-01A (aliquot TCGA-A3-3387-01A-01D-1534-10) from TCGA case TCGA-A3-3387, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 49.1 years (17,920 days).
Specimen TCGA-A3-3387-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90204017-1c55-48e8-b2f7-58599940c9c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3387-11A (Solid Tissue Normal), aliquot TCGA-A3-3387-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aee4dad8-9bc7-4efd-956b-3ba1d8121c00

The open-access MAF lists 79 somatic variants for this specimen: 65 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 13, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, In Frame Del 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.9779C>A p.S3260Y | Missense Mutation (SNP) | VAF 113/386 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV71286429; called by muse, mutect2, varscan2
- ABCB4 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM1313636, COSV55933190; called by muse, mutect2
- ABI2 | c.1124C>A p.P375H (on ENST00000295851 / NM_001375719.1; = p.P308H on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 118/434 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV53694098; called by muse, mutect2, varscan2
- ADGRG2 | c.1566+1G>A p.X522_splice (on ENST00000379869 / NM_001079858.3; = p.X519_splice on NM_005756.4) | Splice Site (SNP) | VAF 48/111 reads (43%) | catalogued as COSV61340142; called by muse, mutect2, varscan2
- AHDC1 | c.4096G>A p.D1366N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs753474234, COSV55940500; called by muse, mutect2, varscan2
- AKAP13 | c.2305A>G p.M769V | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs916383128, COSV63463924; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2695G>T p.V899F | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV51852626; called by muse, mutect2, varscan2
- APOA5 | c.1001dup p.K335Qfs*12 | Frame Shift Ins (INS) | VAF 15/60 reads (25%) | catalogued as rs760743872; called by mutect2, pindel, varscan2
- ARRDC4 | c.403T>G p.Y135D | Missense Mutation (SNP) | VAF 42/569 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV51419714; called by muse, mutect2
- ASIC5 | c.1143A>C p.E381D | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV73332840; called by muse, mutect2, varscan2
- ATP8B2 | c.884C>T p.T295I (on ENST00000672630; = p.T262I on NM_001005855.2) | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.965); catalogued as COSV59247239; called by muse, mutect2
- BCL6 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV51653850; called by muse, mutect2
- C1orf94 | c.1763A>G p.Y588C (on ENST00000488417 / NM_001134734.2; = p.Y398C on NM_032884.5) | Missense Mutation (SNP) | VAF 78/332 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760891248, COSV64914602, COSV64915254; called by muse, mutect2, varscan2
- CASR | c.2132T>A p.F711Y (on ENST00000490131; = p.F788Y on NM_000388.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as CM980304, COSV56139221; called by muse, mutect2, varscan2
- CDC25C | c.1298G>T p.C433F | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV60399544; called by muse, mutect2
- CRISP1 | c.183C>A p.N61K | Missense Mutation (SNP) | VAF 62/295 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59994370; called by muse, mutect2, varscan2
- CSF3R | c.605G>C p.W202S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58969111; called by muse, mutect2
- ECT2L | c.2052C>A p.F684L | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62885837; called by muse, mutect2, varscan2
- EEF1A1 | c.1352T>A p.V451D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV58550236; called by muse, mutect2
- FAM135A | c.3577T>C p.S1193P (on ENST00000370479 / NM_001351599.1; = p.S980P on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV99526491; called by muse, mutect2, varscan2
- GJA9 | c.1000T>G p.S334A | Missense Mutation (SNP) | VAF 67/286 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV62532486; called by muse, mutect2, varscan2
- GPSM1 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61304784; called by muse, mutect2, varscan2
- GRIN2B | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV74206764; called by muse, mutect2, varscan2
- HECW1 | c.3938G>T p.G1313V | Missense Mutation (SNP) | VAF 71/308 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67834636; called by muse, mutect2, varscan2
- INSRR | c.2657A>G p.Y886C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63875229; called by muse, mutect2, varscan2
- JAG2 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV59310935; called by muse, mutect2, varscan2
- LAMP3 | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 204/1052 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369097974; called by muse, mutect2, varscan2
- MICAL3 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 106/438 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV52900995; called by muse, varscan2
- MKRN1 | c.1025T>C p.I342T | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV55437696; called by muse, mutect2
- ORC3 | c.1674C>A p.F558L | Missense Mutation (SNP) | VAF 21/244 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV57641850; called by muse, mutect2
- PADI6 | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.307); catalogued as COSV61884444; called by muse, mutect2, varscan2
- PATE2 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV100653482; called by muse, mutect2
- PBRM1 | c.2335C>T p.Q779* | Nonsense Mutation (SNP) | VAF 33/91 reads (36%) | catalogued as COSV56262778, COSV56280910; called by muse, mutect2, varscan2
- PCLO | c.11357A>C p.E3786A | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61648763; called by muse, mutect2
- PCNA | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 104/433 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.153); catalogued as COSV64770645; called by muse, mutect2, varscan2
- PSG11 | c.809A>G p.Q270R | Missense Mutation (SNP) | VAF 74/351 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV60456496; called by muse, mutect2
- PSMB5 | c.15C>A p.S5R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57800968; called by muse, mutect2, varscan2
- RANBP3L | c.997G>T p.D333Y | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs746839639, COSV56956712; called by muse, mutect2
- ROS1 | c.4321+1G>T p.X1441_splice | Splice Site (SNP) | VAF 67/248 reads (27%) | catalogued as COSV63858005; called by muse, mutect2, varscan2
- RSL1D1 | c.841A>C p.N281H | Missense Mutation (SNP) | VAF 44/384 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.254); catalogued as COSV63078104; called by muse, mutect2, varscan2
- SLC33A1 | c.583A>T p.I195F | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63947396; called by muse, mutect2
- SLC6A12 | c.1778G>A p.G593D | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV62885633; called by muse, mutect2, varscan2
- SLC6A13 | c.914A>G p.K305R | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.243); catalogued as COSV58258291; called by muse, mutect2, varscan2
- TG | c.3293C>A p.P1098Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV55084808; called by muse, mutect2, varscan2
- TOB2 | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285389841, COSV100548481; called by muse, mutect2, varscan2
- TRAM1 | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.18); catalogued as COSV51599158; called by muse, mutect2, varscan2
- TRIO | c.2567T>G p.V856G | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60088049; called by muse, mutect2
- TRIO | c.8012C>A p.S2671Y | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV59991347; called by muse, mutect2, varscan2
- TUBB4A | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV51159728; called by muse, mutect2, varscan2
- UBC | c.1165A>G p.T389A | Missense Mutation (SNP) | VAF 68/370 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV60060296; called by muse, varscan2
- UBE2J2 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 27/328 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.18); catalogued as rs763043223, COSV59573248; called by muse, mutect2
- UBE4B | c.3196C>T p.R1066W (on ENST00000343090 / NM_001105562.3; = p.R937W on NM_006048.5) | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs371058351, COSV99476542; called by muse, mutect2
- WDCP | c.1223T>A p.L408H | Missense Mutation (SNP) | VAF 25/321 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.443); catalogued as COSV54592966; called by muse, mutect2
- ZC3H18 | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); catalogued as rs772268865, COSV56323564; called by muse, mutect2, varscan2
- ZC3H7A | c.2877C>G p.D959E | Missense Mutation (SNP) | VAF 152/559 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63270404; called by muse, mutect2, varscan2
- ZDHHC6 | c.478T>C p.F160L | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV65564832; called by muse, mutect2, varscan2
- ZMYM1 | c.1484T>A p.F495Y | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV63252544; called by muse, mutect2, varscan2
- ZNF112 | c.789T>A p.Y263* (on ENST00000337401 / NM_001083335.2; = p.Y257* on NM_013380.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 47/159 reads (30%) | catalogued as rs769929253, COSV61621078; called by muse, mutect2, varscan2
- ZNF570 | c.1139A>G p.H380R | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57579962; called by muse, mutect2, varscan2
- ZNF804B | c.3502C>T p.H1168Y | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60821349, COSV60838916; called by muse, mutect2, varscan2
- CUL1 | c.1655del p.T552Nfs*28 | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | called by mutect2, pindel, varscan2
- MANSC1 | c.231del p.A78Hfs*4 | Frame Shift Del (DEL) | VAF 74/432 reads (17%) | called by mutect2, pindel, varscan2
- OR5D18 | c.790_792del p.N264del | In Frame Del (DEL) | VAF 15/82 reads (18%) | called by mutect2, pindel, varscan2
- SEC16A | c.1757G>A p.G586D | Missense Mutation (SNP) | VAF 3/62 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.373); called by muse, mutect2
- WASHC2A | c.2577del p.D860Tfs*12 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | called by mutect2, varscan2
- CCDC90B | c.729G>A p.L243= | Silent (SNP) | VAF 23/327 reads (7%) | catalogued as rs200284697, COSV52624526; called by muse, mutect2
- DOCK7 | c.4116T>C p.Y1372= (on ENST00000635253 / NM_001367561.1; = p.Y1341= on NM_033407.3) | Silent (SNP) | VAF 28/286 reads (10%) | catalogued as COSV52013073; called by muse, mutect2
- DSEL | c.267T>A p.S89= | Silent (SNP) | VAF 42/162 reads (26%) | catalogued as COSV59492947; called by muse, mutect2, varscan2
- GRIN2B | c.792G>T p.G264= | Silent (SNP) | VAF 40/127 reads (31%) | catalogued as COSV74206763; called by muse, mutect2, varscan2
- MROH2B | c.1833G>A p.E611= | Silent (SNP) | VAF 41/186 reads (22%) | catalogued as COSV68186675; called by muse, mutect2, varscan2
- PARP14 | c.1239A>T p.I413= | Silent (SNP) | VAF 40/194 reads (21%) | catalogued as COSV71735122; called by muse, mutect2, varscan2
- PDE5A | c.1851T>C p.H617= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as COSV53350429; called by muse, mutect2, varscan2
- PGBD5 | c.1155C>T p.Y385= (on ENST00000525115; = p.Y454= on NM_001258311.2) | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as rs1306224456, COSV58412582; called by muse, mutect2, varscan2
- RAET1E | c.426C>T p.T142= | Silent (SNP) | VAF 40/177 reads (23%) | catalogued as rs572045980, COSV61722720, COSV61722749; called by muse, mutect2, varscan2
- RIC1 | c.2691C>T p.F897= | Silent (SNP) | VAF 45/166 reads (27%) | catalogued as COSV52612152, COSV52615443; called by muse, mutect2, varscan2
- SNTG2 | c.276T>G p.S92= | Silent (SNP) | VAF 60/286 reads (21%) | catalogued as COSV57994558; called by muse, mutect2
- VSNL1 | c.129A>G p.L43= | Silent (SNP) | VAF 63/223 reads (28%) | catalogued as rs768137768, COSV54601404; called by muse, mutect2, varscan2
- ZNF684 | c.846T>C p.Y282= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV65519338; called by muse, mutect2, varscan2
- ATG2A | chr11:64891164 A>G | 3'Flank (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
